Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LM, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LM-01A (Primary Tumor).

ICD-O-3

Carcinoma, Adrenal
Cortical 8370/3

Site: $\textcircled{R}$ Adrenal Gland
Cortex C74.0

gn 2/6/13

Procedure: Right adrenalectomy.

Gross description: Adrenal tumor is 254g; measuring 12 x 6 x 6.5cm.

Diagnosis: Adrenal cortical carcinoma. Weiss score = 7. No LN mets (+0/32).

criteria	W 1/16/13	Yes	No
non-Malignant History			
use is (circle):	$\textcircled{R}$	QUALIFIED	DISQUALIFIED

Source: NCI Genomic Data Commons file 1e5dd344-7007-4124-9043-d5d1bcb81760 (TCGA-OR-A5LM.57A7E2E6-210B-41B1-8C22-9ED4930BCDEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).